Surgical pathology report (de-identified scan), TCGA case TCGA-E1-5302, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-5302-01A (Primary Tumor).

[page 1 of 2]
Clinical History:

Not provided.

Gross Examination:

A. "Brain tumor AF1", received fresh. A 10.5 x 7.0 x 3.0 cm portion of brain parenchyma which on sectioning reveals focally expanded and distorted parenchyma. Representative sections are frozen as AF1 and AF2, the remnants are submitted as A1, A2 respectively. Additional representative sections are submitted as A3-A8.

B. "Brain tumor", received fresh. Multiple fragments of soft tan white brain parenchyma aggregating 5.5 x 4.8 x 1.3 cm. Representative sections are submitted as B1-B3.

Intraoperative Consultation:

- A. Astrocytoma grade II-III, probably grade III in view of the previous biopsy.
- B. Astrocytoma grade II-III, probably grade III in view of the previous biopsy.

Microscopic Examination:

The specimen in container A labeled "brain tumor AF1" and in container B labeled "brain tumor" consists of brain tissue which is infiltrated and replaced by a population of pleomorphic cells with astrocytic features. Some of the cells are fibrillary while others are gemistocytes. Occasional mitotic figures are seen. Although in some areas the endothelial cells are plump no well formed endothelial proliferation is seen and necrosis is not identified.

DIAGNOSIS:

A. "BRAIN TUMOR AF1":

ANAPLASTIC ASTROCYTOMA (WHO GRADE III).

B. "BRAIN TUMOR":

ANAPLASTIC ASTROCYTOMA (WHO GRADE III).

I certify that I personally conducted the diagnostic evaluation of the above

Source: NCI Genomic Data Commons file ff5bae45-cbd8-49c5-8656-29c4eca00925 (TCGA-E1-5302.CD1EF6BC-41BF-4B2C-80DC-AD9C7169F4C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).